FM case AD7524 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/56821119-babe-47d6-9972-476d535b2f91

Female, 55.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vagina; primary biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
